Somatic mutation profile of tumor specimen TCGA-3G-AB14-01A (aliquot TCGA-3G-AB14-01A-11D-A423-09) from TCGA case TCGA-3G-AB14, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 51.3 years (18,733 days).
Specimen TCGA-3G-AB14-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6b0097c-8051-4ee0-8de4-9fe085387cee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3G-AB14-11A (Solid Tissue Normal), aliquot TCGA-3G-AB14-11A-22D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a4353c3-3d42-4f6e-9610-703108d2eaaf

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP1 | c.1071T>A p.S357R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1294200974; called by muse, mutect2
- PPP4R4 | c.2456C>T p.S819L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs267604108, COSV58552837; called by muse, mutect2, varscan2
- XPO4 | c.2005G>A p.G669R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763588509, COSV99688693; called by muse, mutect2, varscan2
- ALG9 | c.1409A>G p.K470R (on ENST00000614444 / NM_001352418.1; = p.K477R on NM_024740.2) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FRAS1 | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP6 | c.3481_3487del p.E1161Lfs*3 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- ZMYM3 | c.1845C>A p.C615* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- ANK3 | c.2352G>A p.Q784= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- SDHAF3 | c.6G>A p.P2= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs566561181; called by muse, mutect2, varscan2
- SLC3A1 | c.1645T>C p.L549= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
